CPTAC case C3L-00445 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f28fc405-1fac-4ee0-b398-e0ddf7b4e639

Demographics
Sex at birth: male; Race: white; Year of birth: 1942; Vital status: Dead; Days to death: 3 days; Year of death: 2017; Cause of death: Not Cancer Related; Country of birth: Bulgaria.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Middle lobe, lung; Age at diagnosis: 74.8 years (27,320 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 3 days; Progression or recurrence: no; Days to last follow up: 3 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5 cm (a second GDC size field records 4 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 25; Margin status: Uninvolved.

Follow-up (1 entry)
- Days to follow up: 3 days; Disease response: Tumor Free.

Other clinical attributes
- Weight: 95 kg; Height: 178 cm; BMI: 29.98.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 40; Cigarettes per day: 20; Tobacco smoking onset year: 1962; Tobacco smoking quit year: 2002; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 40.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00445-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 150 mg; Time between clamping and freezing: 50 minutes; Time between excision and freezing: 35 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00445-25: Section location: Right Middle Lobe; Percent tumor nuclei: 75; Percent necrosis: 20.
- Sample C3L-00445-04: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 100 mg; Time between clamping and freezing: 57 minutes; Time between excision and freezing: 42 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00445-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 100 mg; Time between clamping and freezing: 58 minutes; Time between excision and freezing: 43 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00445-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
